PECGS case C083-000041 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/a6c97028-0e86-4f93-934c-10bc6ec3a860

Demographics
Sex at birth: male; Age at index: 69 years; Year of birth: 1951; Vital status: Dead; Cause of death: Cancer Related; Education level: Some High School or Less.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 68.5 years (25,020 days); AJCC clinical stage: Stage IVA; AJCC pathologic stage: Stage IV; Progression or recurrence: yes; Days to last follow up: 604 days (1.7 years).

Biospecimens (2 samples)
- Sample C083-000041_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000041_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
